Somatic mutation profile of tumor specimen TCGA-VS-A8EC-01A (aliquot TCGA-VS-A8EC-01A-11D-A36J-09) from TCGA case TCGA-VS-A8EC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.5 years (20,286 days).
Specimen TCGA-VS-A8EC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ad8df9-ad1e-4659-ba3d-1fa081901510.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EC-10A (Blood Derived Normal), aliquot TCGA-VS-A8EC-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc807dc7-3380-44bd-bc17-89c5a0b7089e

The open-access MAF lists 157 somatic variants for this specimen: 107 protein-altering or splice-affecting, 48 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 48, Frame Shift Del 4, Splice Site 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.5491G>A p.V1831M (on ENST00000614293; = p.V1801M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99686651; called by muse, mutect2, varscan2
- ABCC9 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99684040; called by muse, mutect2, varscan2
- ABCD1 | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99497142; called by muse, mutect2, varscan2
- ACOT2 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468695; called by muse, mutect2
- ALG13 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV99321437; called by muse, varscan2
- ALLC | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99377327; called by muse, mutect2, varscan2
- ARHGEF15 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs747978063, COSV100729962; called by muse, mutect2, varscan2
- C12orf54 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV100011468; called by muse, mutect2, varscan2
- C16orf71 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs138905202; called by muse, mutect2, varscan2
- CCDC80 | c.1751A>G p.K584R | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV99244104; called by muse, mutect2, varscan2
- CD3G | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV99416388; called by muse, mutect2, varscan2
- CEACAM5 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV55752799, COSV99703682; called by muse, mutect2, varscan2
- CEP128 | c.2614-1G>T p.X872_splice | Splice Site (SNP) | VAF 86/117 reads (74%) | catalogued as COSV99823271; called by muse, mutect2, varscan2
- CEP72 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs752784783, COSV53791827; called by muse, mutect2, varscan2
- CHAC1 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101471054; called by muse, mutect2, varscan2
- CHGA | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs780244559, COSV99380961; called by muse, varscan2
- CHST1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100345875; called by muse, mutect2, varscan2
- CLK4 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs372852819, COSV60318069; called by muse, mutect2, varscan2
- COG2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100794566; called by muse, mutect2, varscan2
- COL6A2 | c.1770G>A p.T590= | Splice Region (SNP) | VAF 19/64 reads (30%) | catalogued as rs150999832, COSV100152798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF3 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159186704, COSV99432345; called by muse, mutect2, varscan2
- CRHBP | c.333+1G>A p.X111_splice | Splice Site (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99169433; called by muse, mutect2, varscan2
- CSNK2A2 | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345112; called by muse, mutect2, varscan2
- CUX2 | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs747760741, COSV55644054; called by muse, mutect2, varscan2
- DHRS9 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as rs774290765, COSV100513289, COSV59141380; called by muse, mutect2, varscan2
- DIPK1A | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100941905; called by muse, mutect2, varscan2
- DSCAML1 | c.2612C>T p.T871M (on ENST00000321322; = p.T811M on NM_020693.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs758143629, COSV58391612; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 162/176 reads (92%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as COSV100668295; called by muse, mutect2, varscan2
- EFCAB14 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs148637456; called by muse, mutect2, varscan2
- ESRRG | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV63156199, COSV63169787; called by muse, mutect2, varscan2
- EYA4 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs868227598, COSV100765066; called by muse, mutect2, varscan2
- F8 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as COSV64270634; called by muse, mutect2, varscan2
- FAXDC2 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100303314; called by muse, mutect2, varscan2
- FO393400.1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99640521; called by muse, varscan2
- FOXE1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1359786027, COSV100909824; called by muse, mutect2, varscan2
- FPGS | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100785186, COSV61229010; called by muse, mutect2
- FUT5 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99398451, COSV99398737; called by muse, mutect2
- GPRASP1 | c.1277G>T p.S426I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100850881; called by muse, mutect2, varscan2
- GSN | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180128559, COSV100375620; called by muse, mutect2, varscan2
- IQCH | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1010034421, COSV60050841; called by muse, mutect2, varscan2
- ITFG1 | c.1435T>A p.Y479N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100278215; called by muse, mutect2, varscan2
- KIAA1210 | c.2176C>G p.Q726E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV101273865; called by muse, varscan2
- KIAA1210 | c.1878C>A p.F626L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV101273867, COSV68175532; called by muse, mutect2, varscan2
- LMO2 | c.370G>A p.A124T (on ENST00000395833 / NM_001142315.2; = p.A193T on NM_005574.4) | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT tolerated (0.63); PolyPhen benign (0.305); catalogued as rs781133624, COSV57645556, COSV99063103; called by muse, mutect2, varscan2
- LRFN5 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as rs1436896951, COSV99982009; called by muse, mutect2, varscan2
- LRRC4B | c.1061T>A p.L354Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100975799; called by muse, mutect2, varscan2
- MAGEA3 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs782715078, COSV100938978, COSV100939016; called by muse, mutect2, varscan2
- MAGEA3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100938977; called by muse, mutect2, varscan2
- MAGI3 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100287760; called by muse, mutect2, varscan2
- MAP3K11 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV100482135; called by muse, mutect2, varscan2
- MINK1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1450189586, COSV100766932; called by muse, mutect2, varscan2
- MPEG1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs182543927, COSV99914869; called by mutect2, varscan2
- MPL | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs971379181, COSV65244568; called by muse, mutect2, varscan2
- MTMR11 | c.771G>A p.P257= (on ENST00000439741 / NM_001145862.2; = p.P185= on NM_181873.3) | Splice Region (SNP) | VAF 24/70 reads (34%) | catalogued as rs587758013, COSV100808650; called by muse, mutect2, varscan2
- MYO1F | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100596248; called by muse, mutect2, varscan2
- NOCT | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 101/106 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99763695; called by muse, mutect2, varscan2
- NOTCH1 | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as rs751007903, COSV53046255; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- NRP1 | c.1127A>G p.N376S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs769749073, COSV55166262; called by muse, mutect2, varscan2
- NT5E | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 92/103 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166062054, COSV57628026; called by muse, mutect2, varscan2
- NYAP2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770289601, COSV99795429; called by mutect2, varscan2
- PCDHA1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65373216; called by muse, mutect2, varscan2
- PCDHA2 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100973347; called by muse, mutect2, varscan2
- PIGT | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99648592; called by muse, mutect2, varscan2
- PKP2 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV99297044; called by muse, mutect2, varscan2
- PLXNA4 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs372771390; called by muse, mutect2, varscan2
- POLR1A | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs778105892, COSV55689512, COSV55690598; called by muse, mutect2, varscan2
- PXDNL | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100680397; called by muse, mutect2, varscan2
- RALGAPA1 | c.4564A>G p.M1522V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99352773; called by muse, mutect2, varscan2
- RIN2 | c.1000A>T p.S334C (on ENST00000255006 / NM_001242581.1; = p.S285C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99656501; called by muse, mutect2, varscan2
- RNF17 | c.1415T>C p.V472A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV99691850; called by muse, mutect2, varscan2
- RNF41 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV100560091; called by muse, mutect2
- RPA1 | c.953-1G>A p.X318_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as rs377571379; called by muse, varscan2
- RPS21 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 62/201 reads (31%) | catalogued as COSV99652876; called by muse, mutect2, varscan2
- RUBCN | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT tolerated (0.49); PolyPhen benign (0.388); catalogued as rs1395641067, COSV99065976; called by muse, mutect2, varscan2
- RYR2 | c.11085G>A p.M3695I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1181977194, COSV100767171; called by muse, mutect2, varscan2
- SEMA3A | c.1746G>C p.E582D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs372833174, COSV54874350, COSV99544653; called by muse, mutect2, varscan2
- SGK3 | c.1136G>C p.S379T | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100616527; called by muse, mutect2, varscan2
- SLC12A8 | c.13T>C p.S5P | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100101654; called by muse, mutect2, varscan2
- SLC6A8 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as CD135580, COSV99465623; called by muse, mutect2, varscan2
- SLFN12 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100512874; called by muse, mutect2, varscan2
- SLITRK5 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.424); catalogued as COSV61522417; called by muse, mutect2, varscan2
- SPSB2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV51290048; called by muse, mutect2, varscan2
- TAS2R7 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.06); catalogued as COSV99553495; called by muse, mutect2
- TCERG1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.018); catalogued as COSV99694278; called by muse, mutect2, varscan2
- THSD1 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99318635; called by muse, mutect2, varscan2
- THSD1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.194); catalogued as COSV51629029, COSV99318636; called by muse, mutect2, varscan2
- TKTL1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV99473625; called by muse, mutect2, varscan2
- TMOD4 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs148248887; called by muse, mutect2, varscan2
- TNIK | c.3826G>T p.V1276L | Missense Mutation (SNP) | VAF 78/84 reads (93%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); catalogued as COSV99454224; called by muse, mutect2, varscan2
- TRAF2 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99916122; called by muse, mutect2, varscan2
- TRIP4 | c.302A>C p.H101P | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99974210; called by muse, mutect2, varscan2
- TTN | c.29552C>T p.T9851M (on ENST00000591111; = p.T8924M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | PolyPhen possibly damaging (0.809); catalogued as rs746275042, COSV59912723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USHBP1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV53105968; called by muse, mutect2, varscan2
- USPL1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs78541462; called by muse, mutect2, varscan2
- VAC14 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs756391496, COSV55757287; called by muse, mutect2
- VIRMA | c.2150G>T p.G717V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99887350; called by muse, varscan2
- VPS13B | c.10756C>T p.R3586W | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs200232124, COSV62147742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS18 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99592211; called by muse, mutect2, varscan2
- ZNF618 | c.1513C>T p.R505C (on ENST00000374126 / NM_001318042.2; = p.R412C on NM_133374.2) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773406327, COSV99928890; called by muse, mutect2, varscan2
- ZNF836 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs769788524, COSV100440498; called by muse, mutect2, varscan2
- AC024592.3 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- CARD11 | c.2267_2269del p.E756del | In Frame Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- FBXL19 | c.1699_1700del p.S567Pfs*119 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by pindel, varscan2
- FSIP2 | c.19584dup p.P6529Tfs*24 | Frame Shift Ins (INS) | VAF 56/102 reads (55%) | called by mutect2, varscan2
- POLA1 | c.3158del p.K1053Rfs*25 | Frame Shift Del (DEL) | VAF 34/208 reads (16%) | called by mutect2, varscan2
- RABGGTA | c.334_349del p.H112* | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- TLE3 | c.1166_1175del p.Y389Sfs*8 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- ACTRT2 | c.501C>T p.V167= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV101007439; called by muse, mutect2, varscan2
- AGRN | c.1449C>T p.N483= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs759844691, COSV101038508; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANO8 | c.285C>T p.I95= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs749671728, COSV99343934; called by muse, mutect2, varscan2
- ARHGAP17 | c.372C>T p.Y124= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs767371613, COSV51508485; called by muse, mutect2
- C10orf71 | c.981C>A p.V327= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100109499; called by muse, mutect2, varscan2
- C2CD5 | c.2376C>T p.V792= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs766338192, COSV100448357, COSV61727649; called by muse, mutect2, varscan2
- CARD10 | c.1689C>T p.S563= | Silent (SNP) | VAF 57/77 reads (74%) | catalogued as rs1355148157, COSV52654697; called by muse, mutect2, varscan2
- CD79A | c.183C>T p.N61= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs781792305, COSV99701895; called by muse, mutect2, varscan2
- CLINT1 | c.426C>T p.D142= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs908128183, COSV99753279; called by muse, mutect2, varscan2
- COG8 | c.1524G>A p.P508= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs376659578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYL1 | c.909C>T p.D303= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs41292237, COSV53417001; called by muse, mutect2, varscan2
- ECH1 | c.141C>T p.L47= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99669421; called by muse, mutect2, varscan2
- FAM71D | c.1266A>G p.E422= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- FILIP1L | c.616C>T p.L206= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100496059; called by muse, mutect2
- FO393400.1 | c.249G>A p.L83= | Silent (SNP) | VAF 46/75 reads (61%) | catalogued as COSV99640524; called by muse, varscan2
- FPR3 | c.456C>T p.F152= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100200508; called by muse, mutect2, varscan2
- GCN1 | c.2013G>T p.L671= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100324486; called by muse, mutect2, varscan2
- GPATCH8 | c.2379A>G p.S793= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100132385; called by muse, mutect2, varscan2
- GPRC5A | c.306G>A p.G102= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99185504; called by muse, mutect2, varscan2
- GTDC1 | c.624G>A p.Q208= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99599090, COSV99601194; called by muse, mutect2, varscan2
- HIPK1 | c.240A>G p.A80= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV101060147; called by muse, mutect2, varscan2
- IBTK | c.1279C>T p.L427= | Silent (SNP) | VAF 59/68 reads (87%) | catalogued as COSV100089823; called by muse, mutect2, varscan2
- IGDCC4 | c.1071C>T p.R357= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100732603; called by muse, varscan2
- IL1RL1 | c.1128C>T p.L376= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV99293444; called by muse, mutect2, varscan2
- KIAA1210 | c.2100C>T p.I700= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV101273866; called by muse, varscan2
- KIR3DL3 | c.321G>A p.S107= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs1436815764; called by muse, mutect2, varscan2
- LATS2 | c.2115G>A p.L705= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs201894248, COSV101231424; ClinVar: likely benign; called by muse, mutect2, varscan2
- LLGL2 | c.1419G>A p.T473= | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as rs371502131; called by muse, mutect2, varscan2
- MAGED2 | c.1539C>T p.A513= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs746132056, COSV99514335; called by muse, mutect2, varscan2
- MAPK11 | c.993G>A p.E331= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs763177148, COSV99298885; called by muse, mutect2, varscan2
- MMS19 | c.778C>T p.L260= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs377682706; called by muse, mutect2, varscan2
- NAA38 | c.66C>T p.S22= (on ENST00000575771 / NM_001320925.2; = p.A9V on NM_032356.5) | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV99640566; called by muse, mutect2, varscan2
- NQO1 | c.54C>T p.F18= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100276528; called by muse, mutect2, varscan2
- NRG3 | c.2034C>T p.S678= (on ENST00000404547 / NM_001370084.1; = p.S654= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100930340; called by muse, mutect2, varscan2
- OR8D2 | c.750C>A p.I250= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100658845; called by muse, mutect2, varscan2
- PIGG | c.552C>T p.F184= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs146375356, COSV56317117; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHA7 | c.3075G>A p.R1025= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs750286166, COSV100261779; called by muse, mutect2, varscan2
- PXDN | c.2742C>T p.N914= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs747969270, COSV99411902; called by muse, mutect2, varscan2
- RC3H1 | c.975G>A p.Q325= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV51203116, COSV99280888; called by muse, mutect2, varscan2
- RIPK1 | c.1191G>A p.Q397= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as COSV52530222; called by muse, mutect2, varscan2
- RYR2 | c.5835C>T p.N1945= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as rs189299988, COSV100767170; ClinVar: benign; called by muse, mutect2, varscan2
- SCARA5 | c.777G>A p.T259= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs148420420; called by muse, varscan2
- SPACA4 | c.240G>A p.R80= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs746783916, COSV99613692; called by muse, mutect2, varscan2
- SPOCD1 | c.1698C>T p.G566= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs772568454, COSV99929337; called by muse, mutect2, varscan2
- SPTBN4 | c.5436G>C p.L1812= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV100149680; called by muse, mutect2, varscan2
- STXBP2 | c.342G>T p.L114= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99656852, COSV99657463; called by muse, mutect2, varscan2
- TUT7 | c.4152G>A p.K1384= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99462247; called by muse, mutect2, varscan2
- ZSCAN18 | c.318G>A p.R106= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV99558965; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827787 C>A | 3'Flank (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100157243, COSV59427837; called by muse, mutect2, varscan2
- SNORD115-33 | n.67G>A | RNA (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
